Somatic mutation profile of tumor specimen TCGA-E3-A3E1-01A (aliquot TCGA-E3-A3E1-01A-11D-A20C-08) from TCGA case TCGA-E3-A3E1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 46.3 years (16,895 days).
Specimen TCGA-E3-A3E1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e52dfd9-b55c-4bda-8f7f-4ec0399e363f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E3-A3E1-10A (Blood Derived Normal), aliquot TCGA-E3-A3E1-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d56d91ed-d769-4542-a2d1-246194c6a92c

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GPR142 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as rs978008949, COSV59519793; called by muse, mutect2
- MSLNL | c.1086G>C p.Q362H | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV53503801; called by muse, mutect2
- MX1 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757142989, COSV55819943; called by muse, mutect2
- NCAPD3 | c.3718G>C p.D1240H | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV73187888; called by muse, mutect2
- ZZEF1 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67558609; called by muse, mutect2
- MRC1 | c.2627A>T p.D876V | Missense Mutation (SNP) | VAF 26/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- TTN | c.57311_57314del p.T19104Rfs*10 (on ENST00000591111; = p.T11680Rfs*10 on NM_003319.4) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2
- MTMR1 | c.1971C>T p.S657= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs1368472543, COSV60937221; called by muse, mutect2, varscan2
